Somatic mutation profile of tumor specimen TARGET-10-PARKLK-09A (aliquot TARGET-10-PARKLK-09A-01D) from TARGET case TARGET-10-PARKLK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (662 days).
Specimen TARGET-10-PARKLK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98dbdd15-c1de-442f-9504-8a2ae7014a0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARKLK-14A (Bone Marrow Normal), aliquot TARGET-10-PARKLK-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d6e64ff-e07d-4f37-adef-b1b03c8305b0

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 3, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs1057519804, COSV62571663; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 25/110 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP1A2 | c.2859T>G p.F953L | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV63404816; called by muse, mutect2, varscan2
- DST | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371964498; called by muse, mutect2, varscan2
- LZTS1 | c.841C>A p.Q281K | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56117665; called by muse, mutect2, varscan2
- NOTCH1 | c.4799T>C p.L1600P | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53025622, COSV53031185; called by muse, mutect2, varscan2
- NTPCR | c.544G>C p.V182L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as rs150667258, COSV64052724; called by muse, mutect2, varscan2
- VLDLR | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66074263; called by muse, mutect2, varscan2
- HAP1 | c.1783G>T p.V595L (on ENST00000310778 / NM_001367460.1; = p.V543L on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); called by muse, mutect2
- PCDHA12 | c.810C>T p.D270= | Silent (SNP) | VAF 35/122 reads (29%) | catalogued as rs1227830598, COSV100250622; called by muse, mutect2, varscan2
- ACR | c.565+632C>A | Intron (SNP) | VAF 14/46 reads (30%) | called by muse, varscan2
- ADAMTSL1 | c.5183-66C>T | Intron (SNP) | VAF 6/18 reads (33%) | catalogued as rs1395970785; called by muse, mutect2, varscan2
- VIP | c.336-118G>T | Intron (SNP) | VAF 20/33 reads (61%) | called by muse, mutect2, varscan2
- ZNF44 | c.*882C>T | 3'UTR (SNP) | VAF 14/75 reads (19%) | called by muse, mutect2, varscan2
